Surgical pathology report (de-identified scan), TCGA case TCGA-KN-8423, project TCGA-KICH (Kidney Chromophobe), tissue source site Harvard, specimen TCGA-KN-8423-01A (Primary Tumor).

[page 1 of 3]
Pathologist: William A. Welch, MD

PATHOLOGIC DIAGNOSIS:

A: SPECIMEN LABELED "LEFT KIDNEY":

RENAL CELL CARCINOMA (5.5 cm), predominantly Chromophobe type, Fuhrman grade IV of IV (in a background of II of IV). See note.
Tumor is well circumscribed and confined to the kidney.
Tumor does not invade renal pelvis.
The vascular and ureteral resection margins are free of tumor

NOTE: Many tumor cells are positive for Hale's colloidal iron (chromophobe component), but the tumor also has features of Oncocytoma; this is consistent with a mixed type tumor.

B: SPECIMEN LABELED "REGIONAL LYMPH NODES":

Six (6) lymph node; no tumor present.

ACC stage (6th Ed): T1b N0 Mx

CLINICAL DATA:

History: 45 year-old with incidental findings of solid mass left kidney.
Operation: Nephrectomy.
Operative Findings: Not provided.
Clinical Diagnosis: Incidental left kidney mass.

TISSUE SUBMITTED:

A/1: Left kidney.
B/2: Regional lymph nodes.

GROSS DESCRIPTION:

The specimen is received fresh, in two parts, each labeled with the patient's name and unit number.

Part A, labeled "#1. Left kidney", consists of a 603.5 gm left nephrectomy specimen including kidney (12.5 x 6.5 x 3.3 cm) and surrounding perirenal fat (hanging from 0.9 cm to 2.2 cm in thickness). Extending from the renal pelvis is a segment of ureter (11.0 cm in length with a diameter ranging from 0.1 cm proximally up to 0.4 cm distally), bifurcated renal vein (averaging 0.4 cm in length x 0.5 cm in diameter), renal artery (0.6 cm x 0.3 cm in diameter). The specimen is inked black and sectioned to exhibit a circumscribed bulging mass (5.5 x 4.8 x 3.7 cm) in the lateral lower pole. The mass is approximately 75% fleshy yellow/tan lobulated and solid with a peripheral component (approximately 25%) which is very fibrotic red/brown to tan/white and centrally hemorrhagic. The mass is 8.5 cm from the ureteral margin, 4.7 cm from the renal artery margin, and 4.1 cm from the renal vein margin. Upon sectioning, the mass exhibits a variegated focally hemorrhagic red/brown to yellow/tan focally fibrotic cut surface and grossly appears to expand but not grossly invade through the renal capsule, pushing into the adjacent perinephric fat and coming to within 0.1 cm of the black inked margin. The mass is approximately 85% solid and 15% friable to necrotic.

The remainder of the renal cortex is tan/brown with a well-defined cortical medullary junction. The pelvocaliceal system exhibits smooth glistening tan urothelium with no masses or lesions identified. The adrenal gland is not present. The perinephric fat is thinly sectioned but no lymph node candidates are identified. The specimen is photographed. Representative sections of tumor were previously given to Cytogenetics, Electron Microscopy, and the

[page 2 of 3]
Pathology Report

Tissue Bank. Representative normal kidney was previously sent for Electron Microscopy, Immunofluorescence, and given to the Tissue Bank.

Micro A1: Ureteral and vascular margins, en face, 4 frags, [REDACTED]

Micro A2: Tumor and capsule and closest approach to black inked margin, 1 frag, RSS.

Micro A3: Tumor capsule and perirenal fat, 1 frag, [REDACTED]

Micro A4: Tumor to include junction of fleshy yellow/tan component with fibrotic red/brown to tan component, 1 frag, RSS.

Micro A5: Tumor and adjacent uninvolved kidney and renal sinus, 1 frag, [REDACTED]

Micro A6: Uninvolved kidney, 1 frag, [REDACTED]

Micro A7: Uninvolved calyx and unremarkable urothelium, 1 frag, [REDACTED]

Part B, labeled "#2. Regional lymph", consists of one fragment of yellow/tan fibrofatty tissue (3.9 x 2.4 x 1.1 cm), which is dissected for lymph node candidates. Eight pink/tan rubbery lymph node candidates (ranging from 0.2 cm to 1.0 cm in greatest dimension) are identified and are entirely submitted as follows:

Micro B1: 2 lymph node candidates, 2 frags, [REDACTED]

Micro B2: 3 lymph node candidates, 3 frags, [REDACTED]

Micro B3: 3 small lymph node candidates, 3 frags, [REDACTED]

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

ADDENDUM FOR KIDNEY PARENCHYMA NOT INVOLVED BY TUMOR

PATHOLOGIC DIAGNOSIS

KIDNEY WITH MILD FOCAL GLOBAL GLOMERULOSCLEROSIS (5%) (SEE NOTE)

ARTERIAL AND ARTERIOLAR SCLEROSIS, WITH SUBINTIMAL HYALINOSIS, (SEE NOTE)

NOTE:

This surgical specimen of non-tumoral kidney does not reveal significant findings in the parenchyma. Namely, the glomeruli show 5% focal global sclerosis and there are no significant changes in the tubulo-interstitial compartment. There is only mild vascular sclerosis and focal intimal hyalinosis present.

MICROSCOPIC DESCRIPTION:

The sample consists of kidney cortex and medulla. There are up to two hundred eighty-three glomeruli present in the sample submitted for light microscopy. Fourteen (14) glomeruli are globally obsolescent (5%). The preserved glomeruli show very mild signs of hypertrophy, with subtle increase in cellularity and mesangial matrix. On PAS and Jones' silver methenamine stain, the glomerular basement membranes appear of normal thickness. No "spikes" or craters are recognized. Tubules are well preserved; occasional PAS-positive casts are seen. The interstitium shows no significant fibrosis or active inflammation. Less than 5% of the sample shows tubular atrophy and interstitial fibrosis, as evidenced on the trichrome stains (AFOG); these areas are mostly subcapsular in location. Arteries and arterioles show focal and mild sclerosis of the wall with subintimal hyalinosis.

[page 3 of 3]
RCET 02-12

Printed: 11/28/2005 10:40

Page: 3 of 3

Source: NCI Genomic Data Commons file 707be64a-1b85-401c-879d-c4a812c77955 (TCGA-KN-8423.D3379505-CDA9-4D23-BC41-9DCA06BE301E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).